Gene-level copy-number profile of tumor specimen TCGA-24-2027-01A from TCGA case TCGA-24-2027, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.6 years (18,835 days).
Specimen TCGA-24-2027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e226211e-4a19-4406-b6e8-45fab717d9c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2027-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4eefcedc-12f5-4bd5-a100-b04073939330

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 21,497; copy number 2: 30,743; copy number 3: 5,227; copy number 4: 1,553; copy number 5: 477; copy number 6: 71; copy number 7: 122; copy number 12: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2027-01): tumor purity 0.9, ploidy 1.85, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:163,460,203–163,612,516, 4 genes (within-gene range 0–1): HMMR, HMMR-AS1, MAT2B, AC010291.1.
- chr8:8,228,595–11,203,671, 74 genes (within-gene range 0–1) (broad region; genes not listed).
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,328,564, 2 genes: PPP1R26P1, PCNPP5.
- chr18:39,655,645–39,678,622, 4 genes: AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 701 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:159,902,045–170,305,977, 122 genes, copy number 7 (broad region; genes not listed).
- chr8:42,896,197–49,907,446, 102 genes, copy number 6–12 (broad region; genes not listed).
- chr8:57,994,509–58,204,279, 1 gene, copy number 5 (within-gene range 4–5): FAM110B.
- chr8:58,091,442–60,281,400, 27 genes, copy number 5: AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8.
- chr11:77,813,319–105,531,697, 449 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,083. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
